Gene-level copy-number profile of tumor specimen CDDP-ABK4-TTP1-A from CDDP_EAGLE case CDDP-ABK4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51 years.
Specimen CDDP-ABK4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d330698b-bccf-4558-9b15-656cbbc7626f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABK4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/ea35607c-41aa-4304-b2bf-e9b0ac3bec88

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 24; copy number 2: 6,753; copy number 3: 12,959; copy number 4: 31,947; copy number 5: 2,804; copy number 6: 2,174; copy number 7: 42; copy number 8: 599; copy number 9: 15; copy number 10: 42; copy number 11: 466; copy number 12: 118; copy number 13: 184; copy number 14: 21; copy number 15: 43; copy number 16: 31; copy number 18: 168.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–2): RNU6-904P, RPS16P3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr12:45,718,046–45,727,775, 1 gene: AC008124.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,088 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,911,350–147,295,734, 42 genes, copy number 10 (within-gene range 5–10): PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2, POLR3GL, TXNIP, HJV, AC239799.2, RNVU1-6, LINC01719, NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15.
- chr1:147,541,501–147,670,524, 3 genes, copy number 11: BCL9, AC242628.1, ACP6.
- chr1:147,928,393–154,155,116, 323 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr1:190,097,658–192,011,260, 14 genes, copy number 9–11: BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1.
- chr1:227,393,554–228,776,865, 81 genes, copy number 11 (broad region; genes not listed).
- chr12:23,108,458–34,249,958, 218 genes, copy number 11–18 (within-gene range 3–18) (broad region; genes not listed).
- chr12:38,078,529–38,087,392, 2 genes, copy number 14: AK6P2, CLUHP8.
- chr12:38,201,566–38,329,721, 5 genes, copy number 9: TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr12:54,230,942–54,497,688, 18 genes, copy number 15: CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1.
- chr12:55,716,036–61,600,843, 184 genes, copy number 13 (within-gene range 8–13) (broad region; genes not listed).
- chr12:63,002,469–71,118,247, 181 genes, copy number 11–18 (broad region; genes not listed).
- chr12:76,115,711–76,139,671, 3 genes, copy number 14: AC233290.2, AC233290.1, RNU6-1271P.
- chr12:79,341,205–79,989,218, 13 genes, copy number 14 (within-gene range 3–14): AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20.
- chr17:28,444,063–28,445,563, 1 gene, copy number 14: AC015917.1.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
